Somatic mutation profile of tumor specimen TCGA-G4-6293-01A (aliquot TCGA-G4-6293-01A-11D-1719-10) from TCGA case TCGA-G4-6293, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Transverse colon; AJCC pathologic stage: Stage III; Age at diagnosis: 49.5 years (18,076 days).
Specimen TCGA-G4-6293-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8b32f03b-c1fa-43e3-8b43-365af57ec9c3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G4-6293-10A (Blood Derived Normal), aliquot TCGA-G4-6293-10A-01D-1719-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c6cfd5ff-20e0-4c2d-b111-ef4103681c11

The open-access MAF lists 131 somatic variants for this specimen: 96 protein-altering or splice-affecting, 34 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 79, Silent 34, Nonsense Mutation 5, Frame Shift Del 3, Splice Region 3, In Frame Del 3, Frame Shift Ins 2, Splice Site 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.2626C>T p.R876* | Nonsense Mutation (SNP) | VAF 25/102 reads (25%) | hotspot (GDC flag); catalogued as rs121913333, CM942020, COSV57320538; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1435C>G p.R479G (on ENST00000281708 / NM_001349798.2; = p.R399G on NM_018315.5) | Missense Mutation (SNP) | VAF 40/169 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747241612, COSV55894141, COSV55894999, COSV55908957; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- GPRIN2 | c.298A>C p.T100P | Missense Mutation (SNP) | VAF 27/87 reads (31%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs7090312; called by muse, mutect2, varscan2
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 215/674 reads (32%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SOX9 | c.499_501del p.K167del | In Frame Del (DEL) | VAF 94/340 reads (28%) | hotspot (GDC flag); called by pindel, varscan2
- ADCY10 | c.3535G>A p.E1179K | Missense Mutation (SNP) | VAF 49/216 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs749299065, COSV63242168, COSV63242440; called by muse, mutect2, varscan2
- ANKRD36B | c.2042T>A p.L681H | Missense Mutation (SNP) | VAF 315/543 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV51534290; called by muse, mutect2, varscan2
- APC | c.4466del p.L1489Yfs*18 | Frame Shift Del (DEL) | VAF 34/135 reads (25%) | catalogued as COSV57327796; called by mutect2, pindel, varscan2
- APC | c.5738T>C p.I1913T | Missense Mutation (SNP) | VAF 83/276 reads (30%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs1413246437, COSV99967329; called by muse, mutect2, varscan2
- ARHGAP33 | c.2981C>T p.P994L | Missense Mutation (SNP) | VAF 207/581 reads (36%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as rs781085186, COSV50131490, COSV99138074; called by muse, mutect2, varscan2
- ARID1A | c.2518C>T p.Q840* | Nonsense Mutation (SNP) | VAF 44/145 reads (30%) | catalogued as COSV61371380; called by muse, mutect2, varscan2
- ATM | c.4516G>A p.V1506M | Missense Mutation (SNP) | VAF 69/337 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.405); catalogued as rs760542469, COSV99586954; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BAG6 | c.1243G>A p.E415K | Missense Mutation (SNP) | VAF 38/109 reads (35%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.576); catalogued as COSV52989977; called by muse, mutect2, varscan2
- BCL2L14 | c.765G>A p.M255I | Missense Mutation (SNP) | VAF 44/167 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as COSV53790176; called by muse, mutect2, varscan2
- C17orf80 | c.1673C>T p.T558M | Missense Mutation (SNP) | VAF 50/209 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs778397466, COSV52145313, COSV52147587; called by muse, mutect2, varscan2
- CCDC178 | c.1099_1101del p.E367del | In Frame Del (DEL) | VAF 16/76 reads (21%) | catalogued as rs1406928816; called by pindel, varscan2
- CDH16 | c.1041G>C p.E347D | Missense Mutation (SNP) | VAF 32/103 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100233815; called by muse, mutect2, varscan2
- CDH9 | c.2156G>T p.R719I | Missense Mutation (SNP) | VAF 112/395 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99143562; called by muse, mutect2, varscan2
- CDK5RAP2 | c.5131C>T p.R1711C | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs747902104, COSV62575787; called by muse, mutect2, varscan2
- CHRM2 | c.744G>T p.M248I | Missense Mutation (SNP) | VAF 55/125 reads (44%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs1428222549, COSV57777059; called by muse, mutect2, varscan2
- CLCN5 | c.1660C>T p.R554W | Missense Mutation (SNP) | VAF 38/144 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as COSV56584309; called by muse, mutect2, varscan2
- CLDN8 | c.607C>T p.R203C | Missense Mutation (SNP) | VAF 92/344 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs367879638; called by muse, mutect2, varscan2
- CPQ | c.1183C>T p.L395F | Missense Mutation (SNP) | VAF 32/126 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.093); catalogued as COSV55151670; called by muse, mutect2, varscan2
- CUL7 | c.1103C>T p.T368I | Missense Mutation (SNP) | VAF 52/164 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as rs751097733, COSV54819269; called by muse, mutect2, varscan2
- DCHS1 | c.262G>A p.V88M | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs749530507, COSV55030177; called by muse, mutect2, varscan2
- DIAPH3 | c.1557G>C p.E519D (on ENST00000400324 / NM_001042517.2; = p.E256D on NM_030932.3) | Missense Mutation (SNP) | VAF 100/576 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.081); catalogued as COSV57373865; called by muse, mutect2, varscan2
- DIP2A | c.3706G>A p.V1236I | Missense Mutation (SNP) | VAF 42/170 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.061); catalogued as rs761203268, COSV59481294; called by muse, mutect2, varscan2
- DMXL2 | c.3488C>T p.P1163L | Missense Mutation (SNP) | VAF 32/125 reads (26%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as rs770147032, COSV51849998, COSV51854306; called by muse, mutect2, varscan2
- EML1 | c.109C>T p.R37C | Missense Mutation (SNP) | VAF 70/222 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs760634692, COSV99214868; called by muse, mutect2, varscan2
- EPHA10 | c.218C>T p.T73M | Missense Mutation (SNP) | VAF 76/289 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60404417; called by muse, mutect2, varscan2
- FAH | c.815T>C p.F272S | Missense Mutation (SNP) | VAF 86/246 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55722340; called by muse, mutect2, varscan2
- FAM47A | c.92C>T p.A31V | Missense Mutation (SNP) | VAF 140/410 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.093); catalogued as COSV60494534; called by muse, mutect2, varscan2
- FAT2 | c.9429C>T p.G3143= | Splice Region (SNP) | VAF 30/81 reads (37%) | catalogued as rs1281542562, COSV55823803; called by muse, mutect2, varscan2
- FGF3 | c.652G>A p.D218N | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.015); catalogued as COSV61926275; called by muse, mutect2
- FNDC1 | c.4486C>T p.R1496W | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.762); catalogued as rs377571503; called by muse, mutect2, varscan2
- HDAC6 | c.3040G>A p.G1014R | Missense Mutation (SNP) | VAF 49/141 reads (35%) | SIFT tolerated (0.39); PolyPhen benign (0.013); catalogued as COSV61929683, COSV61931011; called by muse, mutect2, varscan2
- INTS2 | c.2920G>A p.A974T | Missense Mutation (SNP) | VAF 81/318 reads (25%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV52154365, COSV52155901; called by muse, mutect2, varscan2
- KDM5C | c.1395A>T p.E465D | Missense Mutation (SNP) | VAF 56/215 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0.217); catalogued as COSV64766476; called by muse, mutect2, varscan2
- L3MBTL3 | c.2281A>C p.K761Q | Missense Mutation (SNP) | VAF 64/194 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62387123; called by muse, mutect2, varscan2
- LIF | c.514A>T p.T172S | Missense Mutation (SNP) | VAF 77/249 reads (31%) | SIFT tolerated (0.58); PolyPhen benign (0.023); catalogued as COSV50776836; called by muse, mutect2, varscan2
- MAGEE1 | c.2220G>C p.W740C | Missense Mutation (SNP) | VAF 10/249 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV63910963; called by muse, mutect2
- MDN1 | c.574G>T p.A192S | Missense Mutation (SNP) | VAF 37/144 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.046); catalogued as COSV65524532; called by muse, mutect2, varscan2
- MOV10 | c.1848C>A p.Y616* | Nonsense Mutation (SNP) | VAF 49/157 reads (31%) | catalogued as COSV53518377; called by muse, mutect2, varscan2
- MUC6 | c.497G>A p.R166Q | Missense Mutation (SNP) | VAF 48/137 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0.029); catalogued as rs371792590; called by muse, mutect2, varscan2
- MYH7B | c.2582C>T p.T861I | Missense Mutation (SNP) | VAF 117/274 reads (43%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as rs770471792, COSV53422172; called by muse, mutect2, varscan2
- NCAPD2 | c.139G>A p.A47T | Missense Mutation (SNP) | VAF 57/173 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.038); catalogued as COSV59700787; called by muse, mutect2, varscan2
- NCOA5 | c.64C>T p.R22* | Nonsense Mutation (SNP) | VAF 128/301 reads (43%) | catalogued as COSV51645598; called by muse, mutect2, varscan2
- NEK9 | c.1199C>T p.T400I | Missense Mutation (SNP) | VAF 65/237 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.193); catalogued as COSV53132061; called by muse, varscan2
- NINL | c.2002G>A p.E668K | Missense Mutation (SNP) | VAF 82/260 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as rs1385967440, COSV54005008; called by muse, mutect2, varscan2
- NLRP10 | c.220G>T p.V74F | Missense Mutation (SNP) | VAF 47/177 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as COSV60781063; called by muse, mutect2, varscan2
- OCA2 | c.47C>T p.A16V | Missense Mutation (SNP) | VAF 36/99 reads (36%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.054); catalogued as rs776573914, COSV62349810; called by muse, mutect2, varscan2
- OR10A6 | c.408G>T p.M136I | Missense Mutation (SNP) | VAF 64/201 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV59165465, COSV59166142; called by muse, mutect2, varscan2
- PARVG | c.196C>T p.R66C | Missense Mutation (SNP) | VAF 33/150 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs752515984, COSV63561370; called by muse, mutect2, varscan2
- PCDH9 | c.2147C>A p.T716N | Missense Mutation (SNP) | VAF 51/260 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.696); catalogued as COSV60566356; called by muse, mutect2, varscan2
- PCDHB15 | c.2027C>T p.A676V | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as COSV51092718; called by muse, mutect2, varscan2
- PHF20 | c.2861C>T p.T954M | Missense Mutation (SNP) | VAF 31/181 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as rs776268666, COSV64976544; called by muse, mutect2, varscan2
- PIGM | c.587C>T p.P196L | Missense Mutation (SNP) | VAF 111/386 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV63635799; called by muse, mutect2, varscan2
- PKM | c.553G>A p.V185M | Missense Mutation (SNP) | VAF 44/178 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58789951; called by muse, mutect2, varscan2
- RBM33 | c.2014C>T p.R672W | Missense Mutation (SNP) | VAF 235/481 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1182674363, COSV56634417; called by muse, mutect2, varscan2
- RPRD1B | c.49A>T p.S17C | Missense Mutation (SNP) | VAF 58/233 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV65033411; called by muse, mutect2, varscan2
- RYR2 | c.4603C>T p.P1535S | Missense Mutation (SNP) | VAF 92/309 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1376021262, COSV100769615, COSV63660633; called by muse, mutect2, varscan2
- SEMA5A | c.211G>A p.V71I | Missense Mutation (SNP) | VAF 59/206 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV66798505; called by muse, mutect2, varscan2
- SIN3A | c.628C>T p.Q210* | Nonsense Mutation (SNP) | VAF 147/443 reads (33%) | catalogued as COSV64583803; called by muse, mutect2, varscan2
- SLC41A3 | c.164C>A p.T55N | Missense Mutation (SNP) | VAF 47/179 reads (26%) | SIFT tolerated (0.49); PolyPhen benign (0.057); catalogued as COSV59989130; called by muse, mutect2, varscan2
- SLC43A2 | c.433G>A p.V145M | Missense Mutation (SNP) | VAF 75/220 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0.294); catalogued as rs201908715; called by muse, mutect2, varscan2
- SLC4A10 | c.512G>T p.R171I | Missense Mutation (SNP) | VAF 96/389 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55786779; called by muse, mutect2, varscan2
- SLC7A13 | c.712A>G p.I238V | Missense Mutation (SNP) | VAF 31/102 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.696); catalogued as COSV52535601; called by muse, mutect2, varscan2
- SLFN13 | c.1471G>A p.A491T | Missense Mutation (SNP) | VAF 199/1181 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs754407214, COSV53194331; called by muse, mutect2, varscan2
- SMARCA2 | c.2459G>A p.S820N | Missense Mutation (SNP) | VAF 54/170 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.19); catalogued as COSV61809618; called by muse, mutect2, varscan2
- SOX9 | c.229G>T p.V77F | Missense Mutation (SNP) | VAF 56/197 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55423183, COSV55425778; called by muse, mutect2, varscan2
- SP140L | c.1234G>A p.G412R | Missense Mutation (SNP) | VAF 142/516 reads (28%) | SIFT tolerated (0.39); PolyPhen benign (0.179); catalogued as rs765771290, COSV54745687; called by muse, mutect2, varscan2
- ST6GAL2 | c.571G>A p.D191N | Missense Mutation (SNP) | VAF 20/85 reads (24%) | PolyPhen benign (0.01); catalogued as COSV64529674; called by muse, mutect2, varscan2
- STPG2 | c.874C>T p.R292W | Missense Mutation (SNP) | VAF 109/430 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs199644011, COSV54791860; called by muse, mutect2, varscan2
- TECPR2 | c.2803T>A p.Y935N | Missense Mutation (SNP) | VAF 31/105 reads (30%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.732); catalogued as COSV63971813; called by muse, mutect2, varscan2
- TFR2 | c.33G>A p.A11= | Splice Region (SNP) | VAF 38/95 reads (40%) | catalogued as rs111840506, COSV50516059; called by muse, mutect2, varscan2
- TMEM184C | c.653A>G p.N218S | Missense Mutation (SNP) | VAF 48/188 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.056); catalogued as COSV56854103; called by muse, mutect2, varscan2
- TNR | c.295G>A p.A99T | Missense Mutation (SNP) | VAF 107/368 reads (29%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV99689098; called by muse, mutect2, varscan2
- TNXB | c.2735G>A p.R912Q | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as rs374779610; called by muse, mutect2, varscan2
- TRPS1 | c.246G>T p.E82D (on ENST00000220888 / NM_001330599.2; = p.E95D on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/112 reads (29%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.956); catalogued as COSV55249691; called by muse, mutect2, varscan2
- TSGA10 | c.1485G>T p.Q495H | Missense Mutation (SNP) | VAF 70/218 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.808); catalogued as COSV61824128; called by muse, mutect2, varscan2
- TTN | c.91174C>T p.R30392C (on ENST00000591111; = p.R22968C on NM_003319.4) | Missense Mutation (SNP) | VAF 46/170 reads (27%) | PolyPhen probably damaging (0.998); catalogued as rs755271215, COSV60171779, COSV60466074; called by muse, mutect2, varscan2
- UNC13A | c.1970C>T p.T657M | Missense Mutation (SNP) | VAF 55/151 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.321); catalogued as rs766769666, COSV53200961; called by muse, mutect2, varscan2
- USP3 | c.835G>A p.G279S | Missense Mutation (SNP) | VAF 86/304 reads (28%) | SIFT tolerated (0.88); PolyPhen benign (0.003); catalogued as rs199612777, COSV99165778; called by muse, varscan2
- WDR17 | c.2598G>A p.R866= | Splice Region (SNP) | VAF 44/133 reads (33%) | catalogued as COSV54577765; called by muse, mutect2, varscan2
- XK | c.691T>C p.S231P | Missense Mutation (SNP) | VAF 204/735 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV66120444; called by muse, mutect2, varscan2
- ZNF219 | c.2029C>T p.R677W | Missense Mutation (SNP) | VAF 76/198 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1156340731, COSV53881861; called by muse, mutect2, varscan2
- ZNF283 | c.953C>T p.S318F | Missense Mutation (SNP) | VAF 40/116 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV100190478, COSV61030906, COSV61031564; called by muse, mutect2, varscan2
- ZNF626 | c.584A>G p.H195R | Missense Mutation (SNP) | VAF 58/198 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); catalogued as rs1402609225, COSV74129905; called by muse, mutect2, varscan2
- ZNF93 | c.1097A>C p.K366T | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.557); catalogued as COSV59373738, COSV59375908; called by muse, mutect2, varscan2
- ZXDC | c.2407G>A p.G803S | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0.022); catalogued as rs1384776798, COSV61503631; called by muse, mutect2, varscan2
- AMBP | c.49del p.V17* | Frame Shift Del (DEL) | VAF 38/129 reads (29%) | called by mutect2, pindel, varscan2
- ELF3 | c.198dup p.W67Lfs*25 | Frame Shift Ins (INS) | VAF 14/43 reads (33%) | called by mutect2, varscan2
- GATA6 | c.1505dup p.T503Dfs*5 | Frame Shift Ins (INS) | VAF 56/258 reads (22%) | called by mutect2, pindel, varscan2
- GRM7 | c.2426_2427del p.F809Wfs*44 | Frame Shift Del (DEL) | VAF 54/204 reads (26%) | called by pindel, varscan2
- KDM5C | c.2005_2007del p.E669del | In Frame Del (DEL) | VAF 53/204 reads (26%) | called by mutect2, pindel, varscan2
- TCF7L2 | c.381+2dup p.X127_splice | Splice Site (INS) | VAF 20/58 reads (34%) | called by mutect2, varscan2
- ACSF2 | c.702G>A p.A234= | Silent (SNP) | VAF 39/185 reads (21%) | catalogued as rs745644750, COSV51973263; called by muse, mutect2, varscan2
- ADGRG4 | c.3258T>A p.R1086= | Silent (SNP) | VAF 81/271 reads (30%) | catalogued as COSV54960899; called by muse, mutect2, varscan2
- AGGF1 | c.288G>A p.E96= | Silent (SNP) | VAF 78/222 reads (35%) | catalogued as COSV57229913; called by muse, mutect2, varscan2
- AR | c.807C>T p.Y269= | Silent (SNP) | VAF 41/159 reads (26%) | catalogued as rs767555714, COSV65957236; called by muse, mutect2, varscan2
- B3GALT5 | c.150A>C p.T50= | Silent (SNP) | VAF 49/169 reads (29%) | catalogued as rs777514756, COSV58199565; called by muse, mutect2, varscan2
- BSDC1 | c.891G>A p.E297= | Silent (SNP) | VAF 59/183 reads (32%) | catalogued as COSV61982508; called by muse, mutect2, varscan2
- CHD2 | c.951C>A p.I317= | Silent (SNP) | VAF 42/137 reads (31%) | catalogued as COSV59121190; called by muse, mutect2, varscan2
- CORO6 | c.942G>A p.P314= | Silent (SNP) | VAF 49/164 reads (30%) | catalogued as rs576517494, COSV61471383; called by muse, mutect2, varscan2
- DAPK3 | c.495G>A p.A165= | Silent (SNP) | VAF 79/267 reads (30%) | catalogued as rs777773890, COSV56662573; called by muse, mutect2, varscan2
- EFEMP1 | c.807C>T p.Y269= | Silent (SNP) | VAF 63/263 reads (24%) | catalogued as rs138120227; called by muse, mutect2, varscan2
- EIF4E | c.51A>G p.T17= | Silent (SNP) | VAF 83/270 reads (31%) | catalogued as rs538537081, COSV55187949; called by muse, mutect2, varscan2
- FLG | c.6936T>C p.G2312= | Silent (SNP) | VAF 231/818 reads (28%) | catalogued as COSV64244116; called by muse, mutect2, varscan2
- GPRC5B | c.57G>T p.L19= | Silent (SNP) | VAF 16/63 reads (25%) | catalogued as COSV56027404; called by muse, mutect2, varscan2
- H3-3B | c.204C>T p.F68= | Silent (SNP) | VAF 22/102 reads (22%) | catalogued as rs937733974, COSV54666382; called by muse, mutect2, varscan2
- IQGAP1 | c.3111G>A p.K1037= | Silent (SNP) | VAF 27/86 reads (31%) | catalogued as COSV51587747; called by muse, mutect2, varscan2
- KALRN | c.3126A>G p.A1042= | Silent (SNP) | VAF 55/204 reads (27%) | catalogued as COSV53771604; called by muse, mutect2, varscan2
- KIF26A | c.645G>A p.A215= | Silent (SNP) | VAF 67/176 reads (38%) | catalogued as rs747368135, COSV59468112; called by muse, mutect2, varscan2
- MAPKBP1 | c.486G>A p.V162= | Silent (SNP) | VAF 64/252 reads (25%) | catalogued as COSV52964022; called by muse, mutect2, varscan2
- MKKS | c.1515G>A p.Q505= | Silent (SNP) | VAF 44/213 reads (21%) | catalogued as rs1243429283, COSV61399205; called by muse, mutect2
- MXRA5 | c.8016G>A p.T2672= | Silent (SNP) | VAF 144/470 reads (31%) | catalogued as rs1219617468, COSV54241153; called by muse, mutect2, varscan2
- NBN | c.393T>C p.A131= | Silent (SNP) | VAF 32/126 reads (25%) | catalogued as COSV55374528; called by muse, mutect2, varscan2
- NKRF | c.849C>G p.V283= | Silent (SNP) | VAF 61/217 reads (28%) | catalogued as COSV58662163; called by muse, mutect2, varscan2
- NOTCH3 | c.1785C>T p.G595= | Silent (SNP) | VAF 89/293 reads (30%) | catalogued as COSV54639661; called by muse, mutect2, varscan2
- PASD1 | c.2268G>A p.A756= | Silent (SNP) | VAF 157/518 reads (30%) | catalogued as rs372806683, COSV64855942; called by muse, mutect2, varscan2
- PSMD9 | c.639G>A p.L213= | Silent (SNP) | VAF 90/161 reads (56%) | catalogued as COSV55840007; called by muse, mutect2, varscan2
- QRFP | c.126C>T p.D42= | Silent (SNP) | VAF 54/194 reads (28%) | catalogued as COSV58065022; called by muse, mutect2, varscan2
- RTL1 | c.3714C>T p.D1238= | Silent (SNP) | VAF 82/266 reads (31%) | catalogued as rs763293911, COSV66016696, COSV66017148; called by muse, mutect2, varscan2
- SHE | c.678C>T p.D226= | Silent (SNP) | VAF 89/300 reads (30%) | catalogued as rs745452697, COSV59071083; called by muse, mutect2, varscan2
- SIDT1 | c.2274A>G p.L758= | Silent (SNP) | VAF 16/71 reads (23%) | catalogued as rs143958927; called by muse, mutect2, varscan2
- SLC10A2 | c.357C>T p.V119= | Silent (SNP) | VAF 12/87 reads (14%) | catalogued as rs201634783, COSV55360319, COSV99808284; called by muse, mutect2, varscan2
- SLCO2A1 | c.1875C>T p.S625= | Silent (SNP) | VAF 37/117 reads (32%) | catalogued as COSV60487101; called by muse, mutect2, varscan2
- TNKS2 | c.1239T>C p.N413= | Silent (SNP) | VAF 108/366 reads (30%) | catalogued as COSV65416036; called by muse, mutect2, varscan2
- TRO | c.1920C>T p.R640= | Silent (SNP) | VAF 57/179 reads (32%) | catalogued as rs756724040, COSV51504060; called by muse, mutect2, varscan2
- USP11 | c.1302G>A p.P434= (on ENST00000218348; = p.P391= on NM_001371072.1) | Silent (SNP) | VAF 26/89 reads (29%) | catalogued as rs201389587, COSV99510869; called by muse, mutect2, varscan2
- KRT27 | c.-1C>T | 5'UTR (SNP) | VAF 21/66 reads (32%) | catalogued as COSV100053244; called by muse, mutect2, varscan2
